Surgical pathology report (de-identified scan), TCGA case TCGA-EL-A3ZL, project TCGA-THCA (Thyroid Carcinoma), tissue source site MD Anderson, specimen TCGA-EL-A3ZL-01A (Primary Tumor).

[page 1 of 2]
Reviewer Initials	BB	Date Review: 6/17/12

Surgical Pathology Report

DOB:

Physician:

Accession:

Collected:

Received:

Case type: Surgical Case

DIAGNOSIS

- (A) CONFIRM PARATHYROID:
Parathyroid tissue present

ICD-0-3
carcinoma, papillary, thyroid 8260/3
Site: thyroid, NOS C73.9

- (B) THYROID AND LEVEL 6 CONTENTS
PAPILLARY THYROID CARCINOMA, CONVENTIONAL TYPE

Location: Right lobe
Multi-focal: No
Size = 1.5 cm
Extrathyroidal extension: Absent
Lymphovascular invasion: Present
Resection Margins: Negative
Background Thyroid: Multinodular adenomatous goiter
Lymph nodes:

METASTATIC PAPILLARY THYROID CARCINOMA IN FOUR OF SEVENTEEN LYMPH NODES,
0.4 CM LARGEST FOCUS (4/17)
Extracapsular extension: Absent

hw
6/17/12

- (C) RIGHT LEVELS 3, 4 AND 5:
METASTATIC PAPILLARY THYROID CARCINOMA IN THREE OF EIGHT LYMPH NODES, 0.7 CM LARGEST FOCUS (3/8).
Extracapsular extension present focally

Entire report and diagnosis completed by

COMMENT

Deeper levels examined.

GROSS DESCRIPTION

(A) CONFIRM PARATHYROID - One piece of pink soft tissue (0.2 x 0.1 x 0.1 cm, weight 0.003 grams) is received and entirely submitted for frozen section in A.

*FS/DX: PARATHYROID TISSUE. I

(B) THYROID AND LEVEL 6 CONTENTS - A thyroid specimen consists of right lobe (4.0 x 2.0 x 1.4 cm), left lobe (3.7 x 1.6 x 1.2 cm), isthmus (1.6 x 1.1 x 0.3 cm), and fibroadipose tissue (4.0 x 2.0 x 1.5 cm) inferior to isthmus. The surface of right lobe is nodular and is smooth. The specimen is serially sectioned from superior to inferior. A well-circumscribed white-tan,

[page 2 of 2]
Surgical Pathology Report

DOB:

Physician:

Accession:

Collected:

Pathologist:

Received:

Case type: Surgical Case

granular tumor (1.5 x 1.3 x 1.0 cm) is identified in the lateral aspect of the middle right lobe, and the tumor extends to anterior and posterior capsule. Remainder of the right lobe is unremarkable. Left lobe and isthmus are unremarkable.

Seventeen lymph nodes are identified in the adipose tissue below isthmus, ranging from 0.2 x 0.2 x 0.2 cm to 0.4 x 0.3 x 0.3 cm.

SECTION CODE: B1, isthmus; B2-B6, tumor of right lobe (remainder of tissue entirely submitted in tumor bank); B7, B8, representative section of left lobe (remainder of tissue entirely submitted in); B9, fibroadipose tissue above isthmus, entirely submitted; B10-B13, lymph nodes below isthmus (B10-B12, each contain four lymph nodes; B13, five lymph nodes).

(C) RIGHT LEVEL 3, 4 AND 5 - Multiple fragments of fibroadipose tissue (5.0 x 5.0 x 1.8 cm in aggregate). Nine lymph nodes are identified ranging from 0.2 x 0.2 x 0.1 to 2.0 x 0.8 x 0.6 cm.

SECTION CODE: C1, two lymph nodes; C2, three lymph nodes; C3, two lymph nodes; C4, one lymph node serially sectioned; C5, one lymph node serially sectioned.

CLINICAL HISTORY

Thyroid cancer

SNOMED CODES

T-B6000, M-80503, T-C4200, M-80506,

"Some tests reported here may have been developed and performance characteristics determined by approved by the U.S. Food and Drug Administration."

"These tests have not been specifically cleared or

Released by:

Page 2 of 2	
Surgical Pathology Report	
File under: Pathology	

Source: NCI Genomic Data Commons file e684611d-39ee-4e1d-816c-bebf8010d038 (TCGA-EL-A3ZL.97AE09E6-A2B6-4544-A977-71DB50629A32.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).